Somatic mutation profile of tumor specimen TARGET-10-PARENU-09A (aliquot TARGET-10-PARENU-09A-01D) from TARGET case TARGET-10-PARENU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (703 days).
Specimen TARGET-10-PARENU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77901fa0-d7b2-4e66-99b2-8f131fb7eaaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARENU-10A (Blood Derived Normal), aliquot TARGET-10-PARENU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dfcfa7e-781e-4998-a5f7-cd20fba0e866

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'Flank 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 11/102 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDH8 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104408049, COSV54845838; called by muse, mutect2, varscan2
- GRIP2 | c.950G>A p.R317Q (on ENST00000619221; = p.R220Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs752604236; called by muse, mutect2, varscan2
- HTR4 | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SRRM1 | c.1252C>A p.Q418K | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848006 G>A | 5'Flank (SNP) | VAF 53/181 reads (29%) | called by muse, mutect2, varscan2
- SEMA3B | chr3:50269119 C>T | 5'Flank (SNP) | VAF 2/8 reads (25%) | catalogued as COSV100312946; called by muse, mutect2
- VASP | c.910+47T>A | Intron (SNP) | VAF 27/78 reads (35%) | catalogued as rs766654758; called by muse, mutect2, varscan2
